Surgical pathology report (de-identified scan), TCGA case TCGA-CA-5797, project TCGA-COAD (Colon Adenocarcinoma), tissue source site ILSBio, specimen TCGA-CA-5797-01A (Primary Tumor).

[page 1 of 6]
I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Clinical Information

GENERAL INFORMATION

HISTORY OF PRESENT ILLNESS

Chief Complaints: Abdominal pain > bright red blood in the stool

Symptoms: Weight loss

Clinical Findings:

Performance Scale (Karnofsky Score):

- ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☒ 60-70 Symptomatic, in bed less than 50% of day
☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS

Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 6]
**PAST MEDICAL HISTORY**

Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

**SOCIAL HISTORY**

Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY

Relative	Diagnosis	Age of Diagnosis

LAB DATA

Test	Result	Date	Test	Result	Date
			CEA	☐ Negative ☐ Positive: _____	
Hep B	☒ Negative ☐ Positive: _____	//	CA 15-3	☐ Negative ☐ Positive: _____	
Hep C	☒ Negative ☐ Positive: _____	//	CA 19-9	☐ Negative ☐ Positive: _____	
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____	
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____	

B/T Cell Markers:

[page 3 of 6]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT		
Endoscopy	A tumour was found in the sigmoid colon	
MRI		
Biopsy		

CLINICAL DIAGNOSIS	
Preoperative Clinical Diagnosis	
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis
Clinical Staging	Date of Diagnosis
T ₃ N ₀ M ₀ Stage: II	

Treatment Information

SURGICAL TREATMENT			
Procedure			Date of Procedure
Hemi colectomy			
Primary Tumor			
Organ	Detailed Location	Size	
Colon cancer	Sigmoid	4 x 3 x cm	
Extension of Tumor			
Lymph Nodes			
Description	Location of Lymph Nodes	# of Lymph Nodes	
Palpable, Non-Dissected Lymph Nodes			
Dissected Lymph Nodes			
Distant Metastasis			
Organ	Detailed Location	Size	
Surgical Staging			
T ₃ N ₀ M ₀ Stage: II			

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 6]
Pathology Form

Specimen Information

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
11 min		12 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Colon cancer	4 x 3 x cm	Sigmoid	6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 3 N 0 M 0		Stage: II	
Notes:			

[page 5 of 6]
Microscopic Description

Histological Pattern											
Cell Distribution			+	-	Structural Pattern			+	-		
Diffuse				X	Streaming						
Mosaic					Storiform						
Necrosis					Fibrosis						
Lymphocytic Infiltration				X	Palisading						
Vascular Invasion					Cystic Degeneration						
Clusterized					Bleeding						
Alveolar Formation					Myxoid Change						
Indian File					Psammoma/Calcification						

Cellular Differentiation																			
Squamous			+	-	Adenomatous			+	-	Sarcomatous			+	-	Lymphomatous			+	-
Squamoid Cell					Glandular cell				X	Round Cell					Large Cell				
Spindle Cell					Cell Stratification					Fibroblast					Small Cell				
Keratin					Secretion					Osteoblast					RS Cell/RS Like				
Desmosome					Intracyt. Vacuole					Lipoblast					Inflam. Cell				
Pearl					Gland formation				X	Myoblast					Plasma Cell				

Cellular Differentiation: Well Moderate ☒ Poor

Nuclear Appearance				
Nuclear Atypia:	0	I	II	III
Aniso Nucleosis		X		
Hyperchromatism			X	
Nucleolar Prominent			X	
Multinucleated Giant Cell			X	
Mitotic Activity			X	
Nuclear Grade:				

IHC Data			
Marker	Result	Value	Date
ER	☐ Negative ☐ Positive		
PR	☐ Negative ☐ Positive		
Her-2/neu	☐ Negative ☐ Positive		
B-Cell Marker	☐ Negative ☐ Positive		
T-Cell Marker	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		

Final Pathology Report

Histological Diagnosis: villous adenocarcinoma of the sigmoid colon
(moderately differentiated) **Grade:** II

Comments:

[page 6 of 6]
1. **Histological pattern:**

CELL DISTRIBUTION			STRUCTURAL PATTERN		
	+	-		+	-
Diffuse		☒	Streaming		
Mosaic	☒		Storiform		
Necrosis		☒	Fibrosis		
Lymphocytic Infiltration	☒		Palisading		
Vascular Invasion		☒	Cystic Degeneration		
Clusterized		☒	Bleeding		
Alveolar Formation		☒	Myxoid Change		
Indian File		☒	Psamomma/Calcification		

2. **Cellular features:**

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell			Glandular cell	☒		Round Cell			Large Cell		
Spindle Cell			Cell Stratification	☒		Fibroblast			Small Cell		
Keratin			Secretion	☒		Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole	☒		Lipoblast			Inflam. Cell		
Pearl			Gland formation	☒		Myoblast			Plasma Cell		

Otherwise Specified:

D1 50% D2 50% D3 50% D4 30%

2. **Cellular Differentiation:**

Well	Moderately	Poor
	☒	

3. **Nuclear Atypia:**

Nuclear Appearance	0	I	II	III
Aniso Nucleosis			☒	
Hyperchromatism			☒	
Nucleolar Prominent			☒	
Multinucleated Giant Cell			☒	
Mitotic Activity			☒	
Nuclear Grade				

Histological Diagnosis: Adenocarcinoma, G2

Comments:

Source: NCI Genomic Data Commons file c80f747d-9ad5-43ed-a69c-19e38f598472 (TCGA-CA-5797.2BDDA06B-BBAF-4DB3-995E-AB10CAD0E6E9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).